TARGET case TARGET-30-PAMZGT — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eb4fa400-3697-5cf3-97a0-de06602eacd2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 1.6 years (602 days); Year of diagnosis: 2004; Days to last follow up: 4,213 days (11.5 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: A3973.

Follow-up (2 entries)
- Days to follow up: 603 days (1.7 years); Progression or recurrence anatomic site: Brain, NOS; Days to first event: 603 days (1.7 years); First event: Relapse.
- Days to follow up: 4,213 days (11.5 years); Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (3 samples)
- Samples TARGET-30-PAMZGT-01A, TARGET-30-PAMZGT-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMZGT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 4213
- Protocol: ANBL00B1, A3973
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Site of Relapse: Other, specify: Cranial Fossa into Epidural Space
